Somatic mutation profile of tumor specimen TARGET-40-PALKDP-01A (aliquot TARGET-40-PALKDP-01A-01D) from TARGET case TARGET-40-PALKDP, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 9.3 years (3,388 days).
Specimen TARGET-40-PALKDP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5789d365-9bbc-43f3-8643-615ee46784a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PALKDP-10A (Blood Derived Normal), aliquot TARGET-40-PALKDP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66a56595-dbef-46d5-8def-1f0697fa3513

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, RNA 2, 3'Flank 1, Intron 1, Nonsense Mutation 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMC1 | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471695129; called by muse, mutect2, varscan2
- FAM155A | c.1182G>T p.E394D | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV65593688; called by muse, mutect2, varscan2
- MDGA1 | c.2323C>T p.R775W | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs765612556, COSV51799990; called by muse, mutect2, varscan2
- SLC6A17 | c.488G>C p.W163S | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58993058; called by muse, mutect2, varscan2
- SORCS1 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1318641243, COSV99545002; called by muse, mutect2, varscan2
- TACC2 | c.7636G>T p.A2546S (on ENST00000334433; = p.A624S on NM_006997.4) | Missense Mutation (SNP) | VAF 29/290 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.443); catalogued as rs748599613; called by muse, mutect2
- UGT2A3 | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | catalogued as rs1487272410, COSV52359385, COSV99280171; called by muse, mutect2, varscan2
- ATRX | c.106C>G p.P36A | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CRTAC1 | c.1092C>A p.N364K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- GIPR | c.414G>T p.Q138H | Missense Mutation (SNP) | VAF 113/214 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GIPR | c.415G>T p.V139F | Missense Mutation (SNP) | VAF 116/215 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- IPO13 | c.2542T>C p.C848R | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- LVRN | c.2719del p.D907Tfs*3 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- MRTFB | c.2163G>C p.Q721H | Missense Mutation (SNP) | VAF 82/93 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHGC5 | c.1114T>C p.F372L | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- RIPK2 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- RNF169 | c.943G>C p.V315L | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.087); called by muse, mutect2
- RREB1 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 136/252 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SETD2 | c.7198G>A p.D2400N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TDP2 | c.96T>A p.F32L | Missense Mutation (SNP) | VAF 102/662 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- AKAP12 | c.3063G>A p.P1021= | Silent (SNP) | VAF 41/140 reads (29%) | catalogued as rs200401538; called by muse, mutect2, varscan2
- ALKBH8 | c.1539G>A p.Q513= | Silent (SNP) | VAF 48/257 reads (19%) | called by muse, mutect2, varscan2
- APLP2 | c.1032C>T p.G344= | Silent (SNP) | VAF 57/335 reads (17%) | catalogued as rs541085939, COSV53844193; called by muse, mutect2, varscan2
- CTNND2 | c.2847C>T p.N949= | Silent (SNP) | VAF 79/85 reads (93%) | catalogued as rs983587829; called by muse, mutect2, varscan2
- PNMA3 | c.1068A>C p.P356= | Silent (SNP) | VAF 21/132 reads (16%) | called by muse, mutect2
- STAB2 | c.5919G>C p.R1973= | Silent (SNP) | VAF 51/189 reads (27%) | catalogued as rs780417561, COSV66338017; called by muse, mutect2, varscan2
- WFS1 | c.2275C>T p.L759= | Silent (SNP) | VAF 36/132 reads (27%) | called by muse, mutect2, varscan2
- AC118942.1 | n.333G>T | RNA (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- ANKRD20A11P | n.3351C>T | RNA (SNP) | VAF 10/28 reads (36%) | catalogued as rs1185217443; called by muse, mutect2, varscan2
- CORIN | c.1132+37C>T | Intron (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- MIR1302-3 | chr2:113578382 G>A | 3'Flank (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- TGFB1I1 | c.*15C>T | 3'UTR (SNP) | VAF 11/14 reads (79%) | called by muse, mutect2
